Gene-level copy-number profile of tumor specimen MP2PRT-PANTYP-TMP1-A from MP2PRT case MP2PRT-PANTYP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,138 days).
Specimen MP2PRT-PANTYP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6feabdbe-b695-401f-aea6-cf0d3d797fc8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PANTYP-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/243088e2-ee94-4ffa-8cd3-7e3fcd0c130a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 104; copy number 2: 55,098; copy number 3: 3,186.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,311,808, 7 genes (within-gene range 0–1): TRGC1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
